CCDI case PBCCVU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/10dd1250-ecc9-4af8-903f-45dd71f1aebb

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: External ear; Age at diagnosis: 0.9 years (341 days).

Biospecimens (3 samples)
- Sample 0DON4V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DON50: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DON57: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
